Somatic mutation profile of tumor specimen TCGA-BA-A6D8-01A (aliquot TCGA-BA-A6D8-01A-31D-A31L-08) from TCGA case TCGA-BA-A6D8, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 59.6 years (21,778 days).
Specimen TCGA-BA-A6D8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a5ad738-484a-41a7-918a-5f76e18f5758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6D8-10A (Blood Derived Normal), aliquot TCGA-BA-A6D8-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7fd4b0-0fb8-400c-b9c5-03f0baac0a4f

The open-access MAF lists 119 somatic variants for this specimen: 95 protein-altering or splice-affecting, 20 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 20, Nonsense Mutation 9, Frame Shift Ins 5, Intron 3, Splice Site 3, Frame Shift Del 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.1062dup p.Q355Tfs*12 | Frame Shift Ins (INS) | VAF 29/75 reads (39%) | catalogued as rs1567318022; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.375G>C p.T125= | Splice Region (SNP) | VAF 29/71 reads (41%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.580-1G>A p.X194_splice | Splice Site (SNP) | VAF 178/336 reads (53%) | hotspot (GDC flag); catalogued as COSV53205039, COSV99285668; called by muse, mutect2, varscan2
- ANO4 | c.1523G>A p.G508E (on ENST00000392977 / NM_001286615.2; = p.G473E on NM_178826.4) | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV54608763; called by muse, mutect2, varscan2
- ARHGAP31 | c.3182G>C p.G1061A | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV99957842; called by muse, mutect2, varscan2
- ATRN | c.3704A>G p.K1235R | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.13); catalogued as COSV99497928; called by muse, mutect2, varscan2
- BAZ2B | c.674G>C p.R225T | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT tolerated, low confidence (0.9); PolyPhen probably damaging (0.966); catalogued as COSV100601074; called by muse, mutect2, varscan2
- BCAS1 | c.709G>C p.V237L | Missense Mutation (SNP) | VAF 79/274 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV101006498; called by muse, mutect2, varscan2
- BICC1 | c.620T>A p.L207Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99570984; called by muse, mutect2, varscan2
- CAND1 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV101598295; called by muse, mutect2, varscan2
- CATSPERB | c.273T>A p.S91R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99831902; called by muse, mutect2, varscan2
- CCDC170 | c.140G>A p.S47N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99498961; called by muse, mutect2, varscan2
- CEP126 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 16/35 reads (46%) | catalogued as rs374091656; called by muse, mutect2, varscan2
- CILP2 | c.2116C>T p.R706W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs910721427, COSV99364555; called by mutect2, varscan2
- CLVS1 | c.382G>A p.G128R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs754982582, COSV100370776; called by muse, mutect2, varscan2
- CNTNAP2 | c.3011-1G>C p.X1004_splice | Splice Site (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100673565; called by muse, mutect2, varscan2
- CNTNAP5 | c.3918C>G p.I1306M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101444318, COSV70492613; called by muse, mutect2, varscan2
- COL19A1 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as rs753292294, COSV100507665; called by muse, mutect2, varscan2
- COL5A1 | c.1921G>T p.E641* | Nonsense Mutation (SNP) | VAF 64/102 reads (63%) | catalogued as COSV100880654; called by muse, mutect2, varscan2
- CPA3 | c.1123T>A p.F375I | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99936543; called by muse, mutect2, varscan2
- DMBT1 | c.6309C>A p.N2103K (on ENST00000338354 / NM_001377530.1; = p.N1346K on NM_004406.3) | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100354241; called by muse, mutect2, varscan2
- DNAI1 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.105); catalogued as COSV99647225; called by muse, mutect2, varscan2
- DYNC2LI1 | c.769A>G p.I257V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.147); catalogued as rs1207688675, COSV99571630; called by muse, mutect2, varscan2
- FAAH | c.1350G>T p.E450D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99680334; called by muse, mutect2, varscan2
- FGF8 | c.548C>T p.T183M (on ENST00000344255 / NM_033164.4; = p.T165M on NM_006119.6) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1480224305, COSV60142216; called by muse, mutect2
- FIGN | c.773T>C p.V258A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as COSV100293032; called by muse, mutect2, varscan2
- FLNA | c.776C>T p.T259I | Missense Mutation (SNP) | VAF 47/64 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100775334; called by muse, mutect2, varscan2
- FMNL3 | c.1708C>T p.R570W | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781705688, COSV99527158; called by muse, mutect2, varscan2
- GDI2 | c.1089G>C p.E363D | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV100051170; called by muse, mutect2, varscan2
- HDGFL2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs375013451; called by muse, mutect2, varscan2
- HGF | c.363C>A p.N121K | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.079); catalogued as rs1355838479, COSV55945869; called by muse, varscan2
- ICA1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.334); catalogued as COSV99656000; called by muse, mutect2, varscan2
- ITGA7 | c.3346G>A p.E1116K (on ENST00000555728; = p.E1072K on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV57693848; called by muse, mutect2, varscan2
- ITGAL | c.626C>G p.S209* | Nonsense Mutation (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100776027, COSV100776138; called by muse, varscan2
- ITIH5 | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs763259102, COSV53670529; called by muse, mutect2, varscan2
- KIAA1109 | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371237864; called by muse, mutect2, varscan2
- LRP1 | c.1844A>G p.N615S | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99677571; called by muse, mutect2, varscan2
- LRRC74A | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.189); catalogued as COSV53608107; called by muse, mutect2, varscan2
- MAGEB18 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 14/22 reads (64%) | catalogued as COSV100305657, COSV57465207; called by muse, mutect2, varscan2
- MED25 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs1290551836, COSV100458083; called by muse, mutect2, varscan2
- MEF2C | c.1370G>C p.R457T | Missense Mutation (SNP) | VAF 84/159 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.223); catalogued as COSV100426317, COSV60926099; called by muse, mutect2, varscan2
- MICAL2 | c.5083C>T p.P1695S | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.071); catalogued as COSV99812358; called by muse, mutect2, varscan2
- MYBPC1 | c.1715G>A p.R572Q (on ENST00000550270 / NM_206820.2; = p.R597Q on NM_002465.4) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs149018411, COSV62252673; called by muse, mutect2, varscan2
- MYLK2 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.622); catalogued as rs753089175, COSV65658752; called by muse, mutect2, varscan2
- NOTCH1 | c.414C>A p.C138* | Nonsense Mutation (SNP) | VAF 14/17 reads (82%) | catalogued as COSV99492387; called by muse, mutect2, varscan2
- NOX5 | c.1292T>C p.F431S | Missense Mutation (SNP) | VAF 75/106 reads (71%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV99534900; called by muse, mutect2, varscan2
- NPRL3 | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV67854861; called by muse, mutect2, varscan2
- NUMBL | c.1796G>A p.G599D | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as COSV99425158; called by muse, mutect2
- NUP88 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs551961860, COSV99852039; called by muse, mutect2, varscan2
- OMG | c.1170C>A p.F390L | Missense Mutation (SNP) | VAF 37/263 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757057473, COSV55988545, COSV99907955; called by muse, mutect2, varscan2
- OR10J5 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100604855; called by muse, mutect2, varscan2
- OR4D11 | c.434T>C p.I145T | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100506653; called by muse, mutect2, varscan2
- PCARE | c.399G>T p.E133D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as COSV100527938; called by muse, mutect2, varscan2
- PDZD2 | c.7814C>T p.T2605I | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.342); catalogued as COSV99227026; called by muse, mutect2, varscan2
- PKHD1 | c.2330C>T p.T777M | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as rs564240823, COSV61859047; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POGLUT3 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.055); catalogued as rs759283361, COSV60212213; called by muse, mutect2, varscan2
- PPP2R5E | c.1175A>G p.Y392C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518866; called by muse, mutect2, varscan2
- RAB19 | c.644G>T p.C215F | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99325267; called by muse, mutect2, varscan2
- RASGEF1C | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100746487; called by muse, mutect2, varscan2
- RIMS1 | c.4040T>A p.V1347D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as COSV99331025; called by muse, mutect2, varscan2
- RORB | c.959G>C p.R320P (on ENST00000396204 / NM_001365023.1; = p.R309P on NM_006914.4) | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100974656, COSV65336747; called by muse, mutect2, varscan2
- RUNX1T1 | c.1043G>A p.R348K (on ENST00000265814 / NM_001198628.1; = p.R321K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56137990; called by muse, mutect2
- RYR1 | c.7205G>A p.R2402Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.539); catalogued as rs1316906057, COSV100617192; called by muse, mutect2, varscan2
- SALL1 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99192251; called by muse, mutect2, varscan2
- SDAD1 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 50/218 reads (23%) | catalogued as COSV100668748; called by muse, mutect2, varscan2
- SH2D1A | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100758369; called by muse, mutect2, varscan2
- SHFL | c.323G>T p.R108L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as COSV99464031; called by muse, mutect2, varscan2
- SLAIN2 | c.708C>G p.N236K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.234); catalogued as COSV99971917; called by muse, mutect2
- SLAMF6 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.497); catalogued as COSV100924954; called by muse, mutect2, varscan2
- SMG1 | c.10253A>G p.H3418R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101246936; called by muse, mutect2, varscan2
- STXBP1 | c.590A>T p.D197V | Missense Mutation (SNP) | VAF 61/197 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV100964647; called by muse, mutect2, varscan2
- THOC2 | c.4581C>G p.D1527E | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV99834354; called by muse, mutect2, varscan2
- THUMPD3 | c.520G>T p.E174* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as COSV100560670; called by muse, mutect2, varscan2
- TP53 | c.1100+1G>A p.X367_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as COSV53362644; called by muse, mutect2, varscan2
- TREX2 | c.211G>A p.A71T (on ENST00000334497; = p.A28T on NM_080701.3) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT tolerated (1); PolyPhen benign (0.153); catalogued as COSV100444368; called by muse, mutect2, varscan2
- TRPC6 | c.1355T>C p.I452T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.787); catalogued as COSV100723785; called by muse, mutect2, varscan2
- TRPM3 | c.2472G>T p.K824N (on ENST00000357533 / NM_001366142.2; = p.K667N on NM_020952.6) | Missense Mutation (SNP) | VAF 72/96 reads (75%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.493); catalogued as COSV100678935; called by muse, mutect2, varscan2
- TTI1 | c.2269G>T p.V757F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.528); catalogued as COSV100989779; called by muse, mutect2, varscan2
- TTN | c.20821C>A p.P6941T (on ENST00000591111; = p.P6014T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | PolyPhen benign (0.033); catalogued as COSV100633463, COSV60312179; called by muse, mutect2, varscan2
- TTN | c.19469A>G p.Y6490C (on ENST00000591111; = p.Y5563C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/30 reads (40%) | PolyPhen probably damaging (0.99); catalogued as COSV100633465; called by muse, mutect2, varscan2
- URB2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs115399585, COSV50984434, COSV51005769; called by muse, mutect2, varscan2
- USH2A | c.10628G>T p.R3543L | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV100243526, COSV56348142; called by muse, mutect2, varscan2
- USH2A | c.2462T>C p.V821A | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as rs757681199, COSV100243527; called by muse, mutect2, varscan2
- USP33 | c.2224A>G p.I742V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as COSV62470202; called by muse, mutect2
- WASHC5 | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV59194217; called by muse, mutect2, varscan2
- ZNF418 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.999); catalogued as COSV68675898; called by muse, varscan2
- ZNF536 | c.2203G>A p.V735I | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.006); catalogued as rs375973209; called by muse, mutect2, varscan2
- ZNF578 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101405126; called by muse, mutect2, varscan2
- ASXL1 | c.1616del p.K539Sfs*164 | Frame Shift Del (DEL) | VAF 71/253 reads (28%) | called by mutect2, pindel, varscan2
- GPR179 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-B | c.629dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 37/174 reads (21%) | called by mutect2, pindel, varscan2
- MIS12 | c.439dup p.I147Nfs*14 | Frame Shift Ins (INS) | VAF 25/114 reads (22%) | called by mutect2, pindel, varscan2
- TMEM161B | c.533del p.F178Sfs*9 | Frame Shift Del (DEL) | VAF 14/21 reads (67%) | called by mutect2, varscan2
- WIF1 | c.507_514dup p.I172Kfs*51 | Frame Shift Ins (INS) | VAF 11/43 reads (26%) | called by mutect2, varscan2
- WNT4 | c.524_525dup p.S176Efs*12 | Frame Shift Ins (INS) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- C11orf16 | c.1293G>C p.L431= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100214987; called by muse, mutect2, varscan2
- DNAH7 | c.2818T>C p.L940= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as rs766872187, COSV100418011; called by muse, mutect2, varscan2
- ERN2 | c.2679G>A p.T893= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs201663472, COSV99890340; called by muse, mutect2, varscan2
- EXOC6B | c.264A>G p.E88= | Silent (SNP) | VAF 62/147 reads (42%) | catalogued as COSV99726786; called by muse, mutect2, varscan2
- GPATCH1 | c.2700C>T p.S900= | Silent (SNP) | VAF 22/95 reads (23%) | catalogued as rs575320860, COSV50114186; called by muse, mutect2
- IPO8 | c.3078C>A p.S1026= | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as rs377717299, COSV99805699; called by muse, mutect2, varscan2
- LUZP2 | c.138A>C p.T46= | Silent (SNP) | VAF 23/99 reads (23%) | catalogued as COSV100421614; called by muse, mutect2, varscan2
- MAGEC1 | c.819C>T p.S273= | Silent (SNP) | VAF 69/102 reads (68%) | catalogued as COSV99596712; called by muse, mutect2, varscan2
- MIS18A | c.9C>A p.G3= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV99267155; called by muse, mutect2, varscan2
- MYO15A | c.231C>T p.R77= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99234690; called by muse, mutect2, varscan2
- NCOA6 | c.6039A>T p.P2013= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs1239848612, COSV100750416; called by muse, mutect2, varscan2
- PDILT | c.567G>A p.E189= | Silent (SNP) | VAF 15/157 reads (10%) | catalogued as COSV100199871; called by muse, mutect2, varscan2
- PRORP | c.378A>G p.K126= | Silent (SNP) | VAF 23/44 reads (52%) | catalogued as COSV99156669; called by muse, mutect2, varscan2
- PSKH2 | c.630C>T p.S210= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs376242267; called by muse, mutect2, varscan2
- RECQL4 | c.219A>T p.P73= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV99468356; called by muse, mutect2, varscan2
- RYR1 | c.14529C>T p.G4843= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100617193; called by muse, mutect2, varscan2
- TLE2 | c.1854G>T p.L618= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV99504746; called by muse, mutect2, varscan2
- TNFRSF9 | c.522G>A p.P174= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs770976275, COSV101097391; called by muse, mutect2, varscan2
- YWHAG | c.186C>A p.V62= | Silent (SNP) | VAF 23/149 reads (15%) | catalogued as COSV100297468; called by muse, mutect2, varscan2
- ZAN | c.5505G>A p.P1835= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as rs755450631, COSV100770515; called by muse, mutect2, varscan2
- AP001267.5 | c.-799+5235C>G | Intron (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100329288, COSV56138992; called by muse, varscan2
- NALCN | c.1765-4773T>G | Intron (SNP) | VAF 69/129 reads (53%) | catalogued as COSV99218224; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23166978 G>T | 3'Flank (SNP) | VAF 49/230 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.10360+2716T>C | Intron (SNP) | VAF 24/61 reads (39%) | catalogued as rs1172412088, COSV100633467; called by muse, mutect2, varscan2
